CCDI case PBCHZA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/a71a9e29-157b-4d70-9bbf-0edbc95e2f50

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.9 years (6,177 days).

Biospecimens (2 samples)
- Sample 0DSP2D: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DSP2I: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
